Gene-level copy-number profile of specimen HCM-BROD-0048-C71-85A from HCMI case HCM-BROD-0048-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 66.2 years (24,164 days).
Specimen HCM-BROD-0048-C71-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 10.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9557ce77-8879-4a0f-968d-5cb8c62faeef.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0048-C71-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,711 have no estimate.
https://portal.gdc.cancer.gov/files/3ce41673-2bff-45c3-b49b-dffc26641ac0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 13; copy number 1: 6,613; copy number 2: 48,820; copy number 3: 488; copy number 4: 2,902; copy number 5: 1; copy number 8: 1; copy number 12: 16; copy number 13: 14; copy number 31: 44.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–21,937,651, 1 gene (within-gene range 0–1): MTAP.
- chr9:21,858,910–21,893,857, 2 genes (within-gene range 0–1): AL359922.2, AL359922.3.
- chr9:22,747,700–23,682,662, 6 genes (within-gene range 0–1): CLIC4P1, AC017067.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2.
- chr9:24,905,469–25,678,440, 3 genes: RMRPP5, RN7SKP120, TUSC1.
- chr9:25,937,912–25,938,434, 1 gene: FAM71BP1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 76 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:203,795,623–205,134,950, 44 genes, copy number 31: ZC3H11A, ZBED6, AC114402.2, AC114402.1, RPL35AP5, SNRPE, KRT8P29, HSPE1P6, CBX1P3, LINC00303, AL592146.2, SOX13, AL592146.1, ETNK2, ERLNC1, REN, AL592114.2, KISS1, GOLT1A, PLEKHA6, AL592114.3, AL592114.1, LINC00628, AL606489.1, AL606489.2, PPP1R15B, PIK3C2B, MDM4, AL512306.1, RNA5SP74, AL512306.3, LRRN2, AL512306.2, AL161793.1, RNA5SP75, AL161793.2, AC096675.1, NFASC, AL391822.1, CNTN2, TMEM81, RBBP5, AL583832.1, AC093422.2.
- chr7:54,752,250–55,862,755, 30 genes, copy number 12–13: SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6, AC091812.1, FKBP9P1, RNU6-389P, Metazoa_SRP, SUMO2P3, CICP11, AC091812.3, AC091812.2, PSPHP1, RNU6-1126P, SEPTIN14, AC092647.4, CICP12, AC092647.3.
- chr7:65,814,672–65,814,775, 1 gene, copy number 8: RNU6-912P.
- chr11:127,204–139,612, 1 gene, copy number 5 (within-gene range 2–5): LINC01001.

Autosomal genes at a single copy (total copy number 1): 3,757. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
